Somatic mutation profile of tumor specimen TARGET-20-PASLSD-03A (aliquot TARGET-20-PASLSD-03A-02D) from TARGET case TARGET-20-PASLSD, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (969 days).
Specimen TARGET-20-PASLSD-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2310556-e8aa-4800-aa6b-42946f004499.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASLSD-14A (Bone Marrow Normal), aliquot TARGET-20-PASLSD-14A-02D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64a83bee-6193-418d-8763-aa956085c602

The open-access MAF lists 22 somatic variants for this specimen: 5 protein-altering or splice-affecting, 7 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 7, 3'UTR 7, Missense Mutation 4, 5'Flank 2, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BANP | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs767784511, COSV53741471; called by muse, mutect2, varscan2
- PASK | c.1576G>A p.G526R | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs146166509; called by muse, varscan2
- WT1 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV60066225; called by muse, mutect2, varscan2
- ACOT4 | c.564_569delinsTCAAAG p.A189_Y190delinsQS | Missense Mutation (ONP) | VAF 40/115 reads (35%) | called by pindel, varscan2*
- NUP205 | c.5608C>T p.Q1870* | Nonsense Mutation (SNP) | VAF 77/154 reads (50%) | called by muse, mutect2, varscan2
- CACNA1B | c.831C>T p.C277= | Silent (SNP) | VAF 54/108 reads (50%) | catalogued as rs778540767, COSV99500558; called by muse, mutect2, varscan2
- DOCK8 | c.2760G>A p.K920= | Silent (SNP) | VAF 23/35 reads (66%) | catalogued as rs778993684; called by muse, mutect2, varscan2
- GPRASP1 | c.3819G>T p.L1273= | Silent (SNP) | VAF 107/230 reads (47%) | catalogued as rs374277193; called by muse, mutect2, varscan2
- KMT2D | c.735C>T p.T245= | Silent (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- PTPRF | c.615C>T p.Y205= | Silent (SNP) | VAF 69/136 reads (51%) | catalogued as rs17849125, COSV63447642; called by muse, mutect2, varscan2
- THRAP3 | c.1515C>T p.G505= | Silent (SNP) | VAF 68/144 reads (47%) | catalogued as rs755554289; called by muse, mutect2, varscan2
- XPO5 | c.2925T>C p.V975= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as rs1271200059; called by muse, mutect2, varscan2
- AKR1A1 | chr1:45550817 C>A | 5'Flank (SNP) | VAF 25/58 reads (43%) | catalogued as rs888243742; called by muse, mutect2, varscan2
- ARHGEF40 | c.*262del | 3'UTR (DEL) | VAF 76/179 reads (42%) | called by mutect2, pindel, varscan2
- ATXN1 | c.*5228_*5231delinsA | 3'UTR (DEL) | VAF 32/56 reads (57%) | catalogued as rs1313826922; called by pindel, varscan2*
- ATXN1 | c.*5057dup | 3'UTR (INS) | VAF 85/167 reads (51%) | catalogued as rs1217865143; called by mutect2, varscan2
- LRP6 | c.-59C>T | 5'UTR (SNP) | VAF 15/39 reads (38%) | catalogued as rs1027717462; called by muse, mutect2, varscan2
- MAP3K4 | c.*287G>A | 3'UTR (SNP) | VAF 106/228 reads (46%) | catalogued as rs1393306569; called by muse, varscan2
- NPM1 | chr5:171387800 C>A | 5'Flank (SNP) | VAF 46/93 reads (49%) | catalogued as rs568219237; called by muse, mutect2, varscan2
- REV3L | c.*384A>G | 3'UTR (SNP) | VAF 89/184 reads (48%) | catalogued as rs1460437269; called by muse, mutect2, varscan2
- STOX2 | c.*349G>A | 3'UTR (SNP) | VAF 61/111 reads (55%) | catalogued as rs1282607738; called by muse, mutect2, varscan2
- TPRX1 | c.*382T>C | 3'UTR (SNP) | VAF 48/88 reads (55%) | catalogued as rs1000777598; called by muse, mutect2, varscan2
